Somatic mutation profile of tumor specimen ALCH-ABBR-TTP1-A (aliquot ALCH-ABBR-TTP1-A-1-0-D-A485-36) from ALCHEMIST case ALCH-ABBR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.8 years (29,875 days).
Specimen ALCH-ABBR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c51f77a-5f49-4772-babe-6d209fa84d77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABBR-NB1-A (Blood Derived Normal), aliquot ALCH-ABBR-NB1-A-1-0-D-A485-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f9e3284-b167-469a-8550-6e8c167fc600

The open-access MAF lists 89 somatic variants for this specimen: 52 protein-altering or splice-affecting, 24 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 24, Nonsense Mutation 7, Intron 5, Frame Shift Del 4, 5'UTR 3, RNA 3, Splice Site 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 28/221 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 47/349 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 88/537 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BDP1 | c.4411A>G p.M1471V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs753250902; called by muse, mutect2, varscan2
- CD8A | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV99374430; called by muse, mutect2, varscan2
- CDH9 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs746260289, COSV50253125; called by muse, mutect2, varscan2
- COL4A6 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.02); catalogued as COSV57864193; called by muse, mutect2
- CSMD3 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.192); catalogued as COSV52228776, COSV99853386; called by muse, mutect2, varscan2
- DYSF | c.2695C>A p.L899I | Missense Mutation (SNP) | VAF 51/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177538793; called by muse, mutect2, varscan2
- GRM8 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs61737178, COSV100282191; called by muse, mutect2
- MFAP5 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753225796, COSV100848202, COSV63945864; called by muse, mutect2, varscan2
- NHSL2 | c.1534G>T p.A512S (on ENST00000510661; = p.A878S on NM_001013627.2) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.066); catalogued as rs1261317408; called by muse, mutect2
- OR4C11 | c.506C>G p.P169R | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100155261; called by muse, mutect2
- OR4K13 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 33/248 reads (13%) | catalogued as COSV59860786; called by muse, mutect2, varscan2
- RABEP1 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1449675180; called by muse, mutect2
- SAG | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV68590424; called by muse, mutect2, varscan2
- SETBP1 | c.4213G>T p.E1405* | Nonsense Mutation (SNP) | VAF 99/547 reads (18%) | catalogued as COSV56313320, COSV99952445; called by muse, mutect2, varscan2
- SLC25A21 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV58726498; called by muse, mutect2, varscan2
- ZNF606 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs777270429, COSV100071971; called by muse, mutect2, varscan2
- AHCYL2 | c.1357_1360del p.T453Vfs*8 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel*
- ALPI | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AP1M1 | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- ATRX | c.6157T>A p.F2053I | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- BAHCC1 | c.6925G>A p.A2309T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CEP89 | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- COL5A2 | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 49/371 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.9770C>T p.T3257I (on ENST00000520002; = p.T3256I on NM_033225.6) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CTDSP2 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4F12 | c.525+1G>T p.X175_splice | Splice Site (SNP) | VAF 33/278 reads (12%) | called by muse, mutect2, varscan2
- DISP3 | c.1617C>A p.N539K | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2
- DLGAP4 | c.970C>A p.H324N | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, varscan2
- FAM153B | c.933G>T p.M311I (on ENST00000253490; = p.M234I on NM_001265615.1) | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FN1 | c.7117A>C p.M2373L (on ENST00000359671 / NM_001365524.2; = p.M2342L on NM_002026.4) | Missense Mutation (SNP) | VAF 52/386 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.013); called by muse, varscan2
- GPR4 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2
- HGFAC | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1549L | c.149C>A p.P50H (on ENST00000321505; = p.P347H on NM_012194.3) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NEDD4 | c.353T>G p.L118W | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OR2T1 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PCBP1 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHOSPHO1 | c.509_510del p.R170Lfs*174 | Frame Shift Del (DEL) | VAF 28/182 reads (15%) | called by pindel, varscan2
- PON1 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRSS12 | c.1076G>T p.C359F | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN2 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBM19 | c.1762G>C p.V588L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- RETREG2 | c.1213del p.L405Sfs*4 | Frame Shift Del (DEL) | VAF 48/449 reads (11%) | called by mutect2, pindel, varscan2
- RIN2 | c.1182C>A p.N394K (on ENST00000255006 / NM_001242581.1; = p.N345K on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/496 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPSB4 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ST8SIA4 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYCP2L | c.1922T>A p.L641* | Nonsense Mutation (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- TENM3 | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TEX43 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIMD4 | c.567del p.V190Sfs*11 | Frame Shift Del (DEL) | VAF 56/452 reads (12%) | called by mutect2, pindel, varscan2
- ACAN | c.5769T>C p.Y1923= | Silent (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
- CADM2 | c.430C>T p.L144= (on ENST00000407528 / NM_001167674.2; = p.L146= on NM_153184.4) | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- CDH22 | c.579G>T p.S193= | Silent (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2493C>A p.G831= | Silent (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- FBRS | c.1305G>T p.G435= (on ENST00000287468; = p.G955= on NM_001105079.3) | Silent (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- GPR25 | c.378C>T p.G126= | Silent (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- GPR4 | c.969G>T p.L323= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2
- GZMH | c.639A>G p.Q213= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs1307981334; called by muse, varscan2
- MMP16 | c.1200C>T p.D400= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs749625537, COSV54149139, COSV54180953; called by muse, mutect2, varscan2
- MYH2 | c.1869C>T p.L623= | Silent (SNP) | VAF 53/395 reads (13%) | called by muse, mutect2, varscan2
- NHSL2 | c.1533G>T p.V511= (on ENST00000510661; = p.V877= on NM_001013627.2) | Silent (SNP) | VAF 16/209 reads (8%) | called by muse, mutect2
- OR4C11 | c.507C>A p.P169= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV56353626; called by muse, mutect2
- OR4K13 | c.723A>G p.S241= | Silent (SNP) | VAF 33/249 reads (13%) | called by muse, mutect2, varscan2
- PHF12 | c.30C>T p.I10= | Silent (SNP) | VAF 33/296 reads (11%) | called by muse, mutect2, varscan2
- PKHD1 | c.6909C>T p.I2303= | Silent (SNP) | VAF 43/363 reads (12%) | catalogued as rs1195711232; called by muse, mutect2, varscan2
- PM20D1 | c.1263G>A p.P421= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as rs775577746, COSV65649074; called by muse, mutect2
- SLC17A6 | c.9C>A p.S3= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV54143112; called by muse, mutect2, varscan2
- SMOC1 | c.9C>A p.P3= | Silent (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- SNU13 | c.297C>T p.V99= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- TBC1D2B | c.1113A>T p.T371= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, varscan2
- TM4SF5 | c.495C>T p.A165= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs1351103464; called by muse, mutect2, varscan2
- UBR1 | c.3468A>T p.T1156= | Silent (SNP) | VAF 67/416 reads (16%) | called by muse, mutect2, varscan2
- UBR5 | c.2070C>T p.N690= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- ZNF500 | c.309G>T p.P103= | Silent (SNP) | VAF 28/205 reads (14%) | catalogued as rs752571587; called by muse, mutect2, varscan2
- DSC3 | c.-41C>A | 5'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8481C>A | Intron (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2
- GBA3 | c.59-8480C>A | Intron (SNP) | VAF 40/401 reads (10%) | catalogued as rs1359257221; called by muse, mutect2, varscan2
- GDI1 | c.389-198G>A | Intron (SNP) | VAF 28/308 reads (9%) | catalogued as rs1557198480; called by muse, mutect2
- GSK3B | c.*11del | 3'UTR (DEL) | VAF 31/324 reads (10%) | catalogued as COSV99954691; called by mutect2, pindel
- LINC00174 | n.3324C>T | RNA (SNP) | VAF 23/205 reads (11%) | catalogued as rs369302174; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851219 G>T | 5'Flank (SNP) | VAF 58/418 reads (14%) | called by muse, mutect2, varscan2
- OR5P1P | n.722C>A | RNA (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- OR5P1P | n.721C>A | RNA (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- POLR2C | c.387+32G>C | Intron (SNP) | VAF 40/287 reads (14%) | called by muse, mutect2, varscan2
- PRDM11 | c.656+4435C>G | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- TADA1 | c.-2C>T | 5'UTR (SNP) | VAF 38/196 reads (19%) | catalogued as rs200126309, COSV100902345; called by muse, mutect2, varscan2
- ZNF470 | c.-9C>A | 5'UTR (SNP) | VAF 35/199 reads (18%) | catalogued as rs371751279; called by muse, mutect2, varscan2
